Somatic mutation profile of tumor specimen 0DWD2E from CCDI case PBCLTA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,051 days).
Specimen 0DWD2E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a7276a6-e246-49b9-9fe1-0e73b18bdc23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b0af6c8-ee5e-4c9c-869e-0e06c6217b14

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 316/971 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- FAT1 | c.4301G>A p.G1434E | Missense Mutation (SNP) | VAF 202/1084 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- IER2 | c.464_465del p.E155Gfs*92 | Frame Shift Del (DEL) | VAF 74/314 reads (24%) | called by pindel, varscan2
- ARHGAP18 | c.1923C>T p.D641= | Silent (SNP) | VAF 220/718 reads (31%) | called by muse, varscan2
- MEIS2 | c.*33G>A | 3'UTR (SNP) | VAF 134/376 reads (36%) | catalogued as rs538887435; called by muse, varscan2
